Somatic mutation profile of tumor specimen TCGA-JW-A5VJ-01A (aliquot TCGA-JW-A5VJ-01A-11D-A28B-09) from TCGA case TCGA-JW-A5VJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 56.7 years (20,714 days).
Specimen TCGA-JW-A5VJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f78267fd-5138-492c-ac14-1a2dd1f49a71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JW-A5VJ-10A (Blood Derived Normal), aliquot TCGA-JW-A5VJ-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22cc02a7-2e37-4e29-a0c2-798421a31892

The open-access MAF lists 223 somatic variants for this specimen: 161 protein-altering or splice-affecting, 56 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 56, Nonsense Mutation 16, Intron 6, Nonstop Mutation 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA3 | c.2399G>T p.R800I | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV57052830, COSV57053313, COSV57058609; called by muse, mutect2, varscan2
- ACIN1 | c.2935C>T p.R979* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV52975759; called by muse, mutect2, varscan2
- ACTL6B | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.929); catalogued as rs748105438, COSV50514457, COSV50514641; called by muse, mutect2, varscan2
- ADRA1A | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.773); catalogued as COSV52362707; called by muse, mutect2, varscan2
- AEBP2 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56863299; called by muse, mutect2, varscan2
- AFP | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1194309474, COSV56924949; called by muse, mutect2, varscan2
- AHNAK2 | c.4061C>T p.S1354F | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.385); catalogued as COSV100316752; called by muse, mutect2, varscan2
- AKT2 | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as COSV100251525; called by muse, mutect2
- ANO4 | c.1634A>G p.N545S (on ENST00000392977 / NM_001286615.2; = p.N510S on NM_178826.4) | Missense Mutation (SNP) | VAF 66/93 reads (71%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.696); catalogued as COSV54594182; called by muse, mutect2, varscan2
- APOD | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.23); catalogued as rs5954; called by muse, mutect2, varscan2
- ARGFX | c.402G>C p.K134N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV57681679, COSV57682208, COSV57682652; called by muse, mutect2, varscan2
- AURKA | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53858606; called by muse, mutect2, varscan2
- BMP15 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.659); catalogued as rs781826161, COSV99399324; called by muse, mutect2
- BMP3 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV51083399, COSV51084488; called by muse, mutect2, varscan2
- BTBD9 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV58422636; called by muse, mutect2, varscan2
- C12orf42 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 24/31 reads (77%) | catalogued as COSV59382051; called by muse, varscan2
- C12orf42 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV59382067; called by muse, varscan2
- CAMTA1 | c.1552G>A p.G518R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs140699847; called by muse, mutect2, varscan2
- CARMIL1 | c.3734C>T p.S1245F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.044); catalogued as rs752311740, COSV61516871; called by muse, mutect2, varscan2
- CCDC191 | c.1595G>A p.G532D | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV55671793; called by muse, mutect2, varscan2
- CCDC83 | c.886G>A p.E296K (on ENST00000342404 / NM_001286159.2; = p.E327K on NM_173556.5) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54701505; called by muse, mutect2, varscan2
- CCNT2 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV51472812; called by muse, mutect2, varscan2
- CEP192 | c.2696C>T p.S899L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV100380961, COSV58072641; called by muse, mutect2, varscan2
- CEP192 | c.2906C>T p.S969F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.36); catalogued as rs1401093505, COSV58063317; called by muse, mutect2
- CEP192 | c.2908C>T p.P970S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as rs751064084, COSV58063325; called by muse, mutect2
- CHD2 | c.4793C>G p.S1598* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV67707204, COSV67708615; called by muse, mutect2, varscan2
- CLASRP | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.14); catalogued as rs1362773076, COSV99673725; called by muse, mutect2, varscan2
- CNOT1 | c.3565C>T p.R1189C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV55315943; called by muse, mutect2, varscan2
- CNTNAP4 | c.1559C>G p.S520C | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.962); catalogued as COSV100270444; called by muse, mutect2
- CPT1A | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778008039, COSV55755437; called by muse, mutect2, varscan2
- CSF3R | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58966194; called by muse, mutect2, varscan2
- CUL7 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54816233; called by muse, mutect2, varscan2
- DCAF12L1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100948205; called by muse, mutect2
- DCAF17 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59830206; called by muse, mutect2, varscan2
- DDX58 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65883027, COSV65883275, COSV65883563; called by muse, mutect2, varscan2
- DHTKD1 | c.2338C>T p.Q780* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as rs758531629, COSV53803067, COSV53803241; called by muse, mutect2, varscan2
- DISP2 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99139835; called by muse, mutect2
- DLGAP2 | c.1966G>C p.D656H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs370770474, COSV70097496; called by muse, mutect2, varscan2
- DMXL2 | c.167G>C p.G56A | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51845340; called by muse, mutect2
- DOCK2 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV56955685; called by muse, mutect2, varscan2
- DOK1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99284013; called by muse, mutect2
- DPY19L2 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as COSV60543020; called by muse, mutect2, varscan2
- EIF4A3 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53920363; called by muse, mutect2, varscan2
- EMC1 | c.2245G>T p.D749Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64345692; called by muse, mutect2, varscan2
- ERCC8 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV54015593; called by muse, mutect2, varscan2
- ETF1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV62126905, COSV62127269; called by muse, mutect2, varscan2
- F5 | c.4402G>A p.E1468K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV63123471; called by muse, mutect2, varscan2
- FAT4 | c.3661G>C p.E1221Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67885338; called by muse, mutect2, varscan2
- FBXW7 | c.1522C>T p.Q508* (on ENST00000281708 / NM_001349798.2; = p.Q428* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV55912378; called by muse, mutect2, varscan2
- FGA | c.1772G>C p.R591T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV57395487; called by muse, mutect2, varscan2
- FGFR4 | c.1987G>C p.D663H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV52803020; called by muse, mutect2
- FKBP7 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs1365778021, COSV51846158; called by muse, mutect2, varscan2
- FRMD4A | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as COSV52721691; called by muse, mutect2, varscan2
- GBP5 | c.1101G>T p.M367I | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV100600020; called by muse, mutect2
- GHSR | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV53838710; called by muse, mutect2
- GLS2 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV61737306; called by muse, mutect2, varscan2
- GPR149 | c.2107C>G p.Q703E | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV101078297, COSV67670037; called by muse, mutect2
- GUCY2D | c.3020C>T p.S1007L | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM078230, COSV99643881; called by muse, mutect2
- H2BC4 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV58415706; called by muse, mutect2, varscan2
- H2BW1 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV54220113, COSV54221017, COSV54221415; called by muse, mutect2, varscan2
- HECW1 | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV67828193, COSV67842012; called by muse, mutect2, varscan2
- HEPACAM2 | c.349G>T p.E117* (on ENST00000394468 / NM_001039372.4; = p.E105* on NM_198151.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/93 reads (31%) | catalogued as COSV59059686, COSV59060048; called by muse, mutect2, varscan2
- HIVEP3 | c.3947C>T p.S1316F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99912085; called by muse, mutect2
- HMGCS2 | c.1392G>A p.M464I | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.514); catalogued as rs1344814686, COSV101024745; called by muse, mutect2
- IFNGR1 | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62989751; called by muse, mutect2, varscan2
- IGDCC4 | c.3554G>A p.G1185E | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV100732803; called by muse, mutect2
- IMPDH1 | c.123C>G p.F41L (on ENST00000470772 / NM_001142573.2; = p.F126L on NM_000883.4) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as COSV58315892; called by muse, mutect2, varscan2
- IRF5 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.39); PolyPhen benign (0.086); catalogued as rs767661654, COSV50857426; called by muse, varscan2
- JUNB | c.1043G>C p.*348Sext*159 | Nonstop Mutation (SNP) | VAF 14/113 reads (12%) | catalogued as COSV56877618; called by muse, mutect2, varscan2
- KCNT2 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV54065078, COSV99657109; called by muse, mutect2, varscan2
- KDELR1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV54378583; called by muse, mutect2, varscan2
- KIAA2026 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); catalogued as COSV99424070; called by muse, mutect2, varscan2
- KIAA2026 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.192); catalogued as COSV52388091; called by muse, mutect2, varscan2
- LINGO1 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.023); catalogued as rs1236110595, COSV62436864; called by muse, mutect2, varscan2
- LINGO3 | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV68261260; called by muse, mutect2, varscan2
- LMO7 | c.2711C>T p.S904F (on ENST00000357063; = p.S585F on NM_005358.5) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV58535315, COSV58547175; called by muse, mutect2
- LRRC3 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1289907108, COSV52399195; called by muse, mutect2, varscan2
- LRRC66 | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1177047455, COSV58633395; called by muse, mutect2, varscan2
- MACF1 | c.9226G>A p.E3076K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV57118997; called by muse, mutect2, varscan2
- MAGEA11 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | catalogued as COSV60755335; called by muse, mutect2, varscan2
- MAN2B1 | c.1054C>T p.L352F | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV55473483, COSV99666855; called by muse, mutect2
- MAP7D2 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65527021; called by muse, mutect2, varscan2
- MAPK6 | c.1825C>T p.Q609* | Nonsense Mutation (SNP) | VAF 21/96 reads (22%) | catalogued as COSV55929818; called by muse, mutect2, varscan2
- METTL21C | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99940003; called by muse, mutect2
- MISP | c.1747G>C p.D583H | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV99296718; called by muse, mutect2
- MKI67 | c.2844G>A p.M948I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100896382; called by muse, mutect2
- MOAP1 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as COSV99365674; called by muse, mutect2
- MOB3C | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV54719099, COSV54720283; called by muse, mutect2, varscan2
- MTUS2 | c.3247G>A p.E1083K (on ENST00000612955 / NM_001366650.1; = p.E62K on NM_015233.6) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); catalogued as COSV60158123; called by muse, mutect2, varscan2
- MUC16 | c.27434C>G p.S9145C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV101198359, COSV67462435, COSV67480710; called by muse, mutect2, varscan2
- MUC16 | c.16417C>G p.Q5473E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67453878, COSV67462441; called by muse, mutect2, varscan2
- MYH2 | c.3556G>A p.E1186K | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV55436897; called by muse, mutect2, varscan2
- NKIRAS2 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV56917799; called by muse, mutect2, varscan2
- NMT2 | c.1356C>G p.F452L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65382103; called by muse, mutect2, varscan2
- NMT2 | c.1087C>A p.H363N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV65382109; called by muse, mutect2, varscan2
- NOTCH2 | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56690171; called by muse, mutect2, varscan2
- NUP188 | c.4039C>T p.Q1347* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV65361834; called by muse, mutect2, varscan2
- OPALIN | c.271C>G p.H91D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.055); catalogued as COSV64520536; called by muse, mutect2, varscan2
- OR1D5 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV73859506; called by muse, mutect2, varscan2
- OR8K1 | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.616); catalogued as COSV54402307; called by muse, mutect2
- PACSIN3 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1018179911, COSV54065900; called by muse, mutect2, varscan2
- PCDHB5 | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.244); catalogued as COSV50648006; called by muse, mutect2, varscan2
- PCDHGA2 | c.1075G>C p.D359H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as COSV53937516, COSV53940629; called by muse, mutect2, varscan2
- PDE7B | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.497); catalogued as COSV57496416; called by muse, mutect2, varscan2
- PHKA2 | c.3005G>C p.R1002T | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV66053695; called by muse, mutect2, varscan2
- PLRG1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV57423378; called by mutect2, varscan2
- PMEL | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV59384413; called by muse, mutect2, varscan2
- POLE | c.2551G>C p.E851Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57679363, COSV57684052; called by muse, mutect2, varscan2
- PPL | c.2556C>G p.I852M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.347); catalogued as COSV52167730, COSV52173634; called by muse, mutect2, varscan2
- PPP2R5C | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV100159307; called by muse, mutect2
- PPP2R5E | c.1226A>G p.N409S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV61741620; called by muse, mutect2, varscan2
- PRDM8 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100325060, COSV60203024; called by muse, mutect2
- PSMB11 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs750496396, COSV68430047; called by muse, mutect2, varscan2
- PTPRF | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.486); catalogued as COSV63444594; called by muse, mutect2, varscan2
- RAB40C | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 60/112 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50193417, COSV99937696; called by muse, mutect2, varscan2
- RFX2 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV57941138; called by muse, mutect2, varscan2
- RGS12 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV60909409; called by muse, mutect2
- RNF217 | c.1277G>A p.C426Y (on ENST00000521654 / NM_001286398.2; = p.C134Y on NM_152553.5) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV51575638; called by muse, mutect2, varscan2
- RPAIN | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as rs749948737, COSV56705003; called by muse, mutect2, varscan2
- RPN1 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.033); catalogued as COSV56189852; called by muse, mutect2, varscan2
- RSBN1 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54732181, COSV54735573; called by muse, mutect2, varscan2
- SDCCAG8 | c.1427G>A p.R476K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs761873846, COSV59408375; called by muse, mutect2, varscan2
- SEC16B | c.1984G>C p.E662Q | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV100381445; called by muse, mutect2
- SEPTIN2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100764926; called by muse, mutect2
- SEPTIN2 | c.446G>A p.C149Y | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100764927; called by muse, mutect2
- SERPINF2 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60664292; called by muse, mutect2, varscan2
- SGCD | c.346G>A p.D116N (on ENST00000435422 / NM_001128209.2; = p.D117N on NM_000337.5) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV61907824; called by muse, mutect2, varscan2
- SHPRH | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.024); catalogued as COSV51608538; called by muse, mutect2, varscan2
- SIX4 | c.708C>G p.N236K | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV53671370; called by muse, mutect2
- SLC19A1 | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60754372, COSV60757106; called by muse, mutect2, varscan2
- SLC30A1 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as rs1411601405, COSV65360484, COSV65360952; called by muse, mutect2
- SLC4A10 | c.2684C>T p.S895L (on ENST00000446997 / NM_001354461.2; = p.S865L on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1335514018, COSV55776037; called by muse, mutect2, varscan2
- SNAI1 | c.692C>G p.S231* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV54863925; called by muse, mutect2, varscan2
- SOS2 | c.2377C>T p.L793F | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.228); catalogued as COSV53566953; called by muse, mutect2, varscan2
- SPTLC3 | c.816C>G p.F272L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV65465203; called by muse, mutect2, varscan2
- TAF1B | c.166A>C p.K56Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55155805; called by muse, mutect2
- TENM1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.783); catalogued as COSV64430922; called by muse, mutect2, varscan2
- TEX30 | c.645G>A p.W215* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as rs1311929784, COSV65696733; called by muse, mutect2
- TMEM181 | c.935G>C p.R312T | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65562999; called by muse, mutect2, varscan2
- TNFRSF8 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.132); catalogued as COSV55796117; called by muse, mutect2, varscan2
- TNS3 | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60790369; called by muse, mutect2, varscan2
- TPP2 | c.2956G>A p.V986I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV65752374; called by muse, mutect2
- TRAPPC10 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99378405; called by muse, mutect2, varscan2
- TRPC5 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53289316; called by muse, mutect2, varscan2
- TRPM6 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV62508775; called by muse, mutect2, varscan2
- UBAP2L | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55171795; called by muse, mutect2, varscan2
- UBE3A | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.306); catalogued as COSV51667855; called by muse, mutect2
- VPS13A | c.1863G>C p.L621F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100652497, COSV62428956; called by muse, mutect2, varscan2
- YIPF1 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV50777147; called by muse, mutect2, varscan2
- ZNF112 | c.1367C>G p.S456* (on ENST00000337401 / NM_001083335.2; = p.S450* on NM_013380.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV61619833; called by muse, mutect2, varscan2
- ZNF12 | c.1909G>C p.E637Q (on ENST00000405858 / NM_016265.4; = p.E599Q on NM_006956.3) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as COSV61244174; called by muse, mutect2, varscan2
- ZNF331 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99467120; called by muse, mutect2, varscan2
- ZNF382 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV53087998, COSV99498196; called by muse, mutect2, varscan2
- ZNF384 | c.1734G>C p.*578Yext*13 (on ENST00000361959; = p.*517Yext*13 on NM_133476.5) | Nonstop Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as COSV58554811, COSV58555081; called by muse, mutect2, varscan2
- ZNF578 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV69736423; called by muse, mutect2, varscan2
- ZNF583 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV99382044; called by muse, mutect2
- ZNF646 | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 22/32 reads (69%) | catalogued as COSV54923989; called by muse, mutect2, varscan2
- C17orf50 | c.369G>T p.E123D | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); called by muse, mutect2
- PRAMEF14 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.997); called by muse, mutect2
- RACGAP1 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.419); called by muse, mutect2
- ABCC1 | c.1749C>T p.F583= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as rs1325918780, COSV60693310; called by muse, mutect2, varscan2
- APBB3 | c.219G>A p.T73= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs751347268, COSV60052224; called by muse, mutect2, varscan2
- APPL2 | c.1170G>A p.L390= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV51588518, COSV51589971; called by muse, mutect2, varscan2
- ATP2B1 | c.2958C>T p.N986= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1005125190, COSV53814472; called by muse, mutect2, varscan2
- ATP8B2 | c.510C>T p.I170= (on ENST00000672630; = p.I137= on NM_001005855.2) | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as COSV59245839, COSV59247133; called by muse, mutect2, varscan2
- BCR | c.726C>G p.V242= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV59930732; called by muse, mutect2, varscan2
- BIN3 | c.138G>A p.K46= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV52384332; called by muse, mutect2, varscan2
- CAAP1 | c.765C>G p.L255= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV61700638; called by muse, mutect2, varscan2
- CATSPER2 | c.633C>T p.I211= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV58660718; called by muse, mutect2, varscan2
- CSPP1 | c.1356C>T p.L452= (on ENST00000676605; = p.L411= on NM_024790.6) | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV51583826; called by muse, mutect2, varscan2
- DDX17 | c.480G>A p.V160= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV53252183; called by muse, mutect2, varscan2
- ECI1 | c.501G>A p.A167= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs966272901, COSV57043669, COSV57043812; called by muse, mutect2, varscan2
- FCN1 | c.879C>T p.L293= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV65662238; called by muse, mutect2, varscan2
- GLRA2 | c.141C>T p.F47= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV54338040, COSV54339914; called by mutect2, varscan2
- GNPTG | c.501C>T p.L167= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs756686252, COSV50189984; called by muse, mutect2, varscan2
- GRIN1 | c.825G>A p.K275= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100160667, COSV59294986; called by muse, mutect2
- GSR | c.648C>T p.S216= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV55319813; called by muse, mutect2
- IGHMBP2 | c.1692C>T p.V564= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs746048688, COSV54822030; called by muse, mutect2, varscan2
- IL25 | c.303C>T p.L101= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV59305642; called by mutect2, varscan2
- IL3RA | c.324G>A p.E108= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV58431008, COSV58431089; called by muse, mutect2, varscan2
- ILF3 | c.759C>G p.L253= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV99139523; called by muse, mutect2, varscan2
- IQCB1 | c.174C>T p.L58= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV60437199; called by muse, mutect2, varscan2
- LIAS | c.225G>A p.V75= (on ENST00000261434 / NM_001363700.2; = p.E107K on NM_006859.4) | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV54695591; called by muse, mutect2, varscan2
- LYN | c.1137C>G p.L379= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV70205619; called by mutect2, varscan2
- MACF1 | c.12606C>T p.F4202= (on ENST00000372915; = p.F2135= on NM_012090.5) | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs746742941, COSV57104231; called by mutect2, varscan2
- MAFF | c.156C>G p.L52= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV58299018; called by muse, mutect2, varscan2
- MASP1 | c.1455C>T p.I485= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs755157142, COSV61826027; called by muse, mutect2, varscan2
- MTO1 | c.1119G>T p.V373= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100940386; called by muse, mutect2
- NUDT22 | c.534G>A p.V178= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs139747440, COSV54173157; called by muse, mutect2, varscan2
- OR1S1 | c.705C>T p.I235= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100515336; called by muse, mutect2, varscan2
- PITX2 | c.210G>A p.K70= (on ENST00000354925 / NM_001204397.1; = p.K77= on NM_000325.6) | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV100146254; called by muse, mutect2
- PLCH2 | c.69C>T p.L23= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as rs775427357, COSV99615923; called by muse, mutect2
- PLPPR4 | c.1041G>A p.L347= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV64565555; called by muse, mutect2, varscan2
- PNKP | c.370C>T p.L124= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV55586924, COSV55587606; called by muse, mutect2, varscan2
- POC1B | c.1014A>G p.E338= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV57964643; called by muse, mutect2, varscan2
- RRS1 | c.822C>T p.V274= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV52554940; called by muse, mutect2, varscan2
- RTN4IP1 | c.172C>A p.R58= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV64687410, COSV64687907; called by muse, mutect2, varscan2
- RTN4RL2 | c.1158C>T p.P386= | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as rs1189595308, COSV58651658, COSV58651992; called by muse, mutect2, varscan2
- SCG2 | c.1791C>T p.L597= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV59538863, COSV59538870; called by muse, mutect2, varscan2
- SFRP1 | c.792C>G p.L264= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV55171642, COSV55173545; called by muse, mutect2, varscan2
- SLC19A1 | c.1452G>A p.L484= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1367735421, COSV100229282, COSV60588410, COSV60592826; called by muse, mutect2, varscan2
- SLC19A1 | c.525C>T p.V175= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV60754358; called by muse, mutect2, varscan2
- SLC46A3 | c.1095C>T p.F365= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV57180000, COSV57181649; called by muse, mutect2, varscan2
- SLC4A8 | c.1422C>G p.L474= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV60651376; called by muse, mutect2, varscan2
- SPHK2 | c.1752C>T p.F584= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV55336953; called by muse, varscan2
- SPHK2 | c.1824C>T p.F608= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs1281078848, COSV55336983; called by muse, varscan2
- TACC3 | c.2079G>A p.Q693= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1331344735, COSV57604387; called by muse, mutect2, varscan2
- TAS1R2 | c.1050C>T p.L350= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV64744395; called by muse, mutect2, varscan2
- TMEM59 | c.450C>T p.F150= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV52373870; called by muse, mutect2, varscan2
- TRIM35 | c.1455C>T p.I485= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs770115119, COSV59522774; called by muse, mutect2, varscan2
- TRPM3 | c.3336C>G p.L1112= (on ENST00000357533 / NM_001366142.2; = p.L967= on NM_020952.6) | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100677104; called by muse, mutect2, varscan2
- UBN1 | c.1584G>A p.K528= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV52167725; called by muse, mutect2, varscan2
- WRN | c.3783C>T p.I1261= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV53299460; called by muse, mutect2, varscan2
- ZDHHC8 | c.534G>T p.L178= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV57710008; called by muse, mutect2
- ZFC3H1 | c.2253G>A p.P751= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs556938688, COSV101110442; called by muse, varscan2
- ZNF655 | c.228C>T p.L76= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV53158643; called by muse, mutect2, varscan2
- CADPS | c.2582-907C>T | Intron (SNP) | VAF 5/12 reads (42%) | catalogued as COSV51877582; called by muse, mutect2, varscan2
- MAGED2 | c.1272-188C>T | Intron (SNP) | VAF 49/200 reads (25%) | catalogued as COSV54497693; called by muse, mutect2, varscan2
- PPM1K | c.542-2169C>A | Intron (SNP) | VAF 5/21 reads (24%) | catalogued as COSV55795717; called by muse, mutect2
- TCP10L3 | n.2719+1115C>T | Intron (SNP) | VAF 17/71 reads (24%) | catalogued as COSV64750711, COSV64752027; called by muse, mutect2, varscan2
- TMC5 | c.1049-3449C>G | Intron (SNP) | VAF 7/36 reads (19%) | catalogued as COSV54903587; called by muse, mutect2, varscan2
- TMC5 | c.1049-3285C>G | Intron (SNP) | VAF 16/51 reads (31%) | catalogued as COSV54903598; called by muse, mutect2, varscan2
